Somatic mutation profile of tumor specimen TCGA-BG-A0VX-01A (aliquot TCGA-BG-A0VX-01A-11D-A122-09) from TCGA case TCGA-BG-A0VX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 58.7 years (21,425 days).
Specimen TCGA-BG-A0VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24f262a9-ee1b-40d2-8167-bd3f5235484f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0VX-10A (Blood Derived Normal), aliquot TCGA-BG-A0VX-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/240596a8-11df-4b18-bef6-cf8045f1f181

The open-access MAF lists 216 somatic variants for this specimen: 158 protein-altering or splice-affecting, 56 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 56, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 3, Intron 1, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 57/169 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.1652+1G>A p.X551_splice | Splice Site (SNP) | VAF 39/145 reads (27%) | catalogued as rs281865470, CS124331, COSV52267422, COSV52272538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 72/229 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 41/190 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLE | c.1270C>G p.L424V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs483352909, CM1212502, COSV57673603, COSV57691098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACR | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53361795; called by muse, mutect2, varscan2
- ADIPOR2 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63947506; called by muse, mutect2, varscan2
- AFAP1L1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747689307, COSV57047289; called by muse, mutect2, varscan2
- AFF2 | c.2572A>G p.I858V | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs782744749, COSV54004022, COSV99663790; called by muse, mutect2, varscan2
- AGAP4 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1238585220; called by muse, mutect2, varscan2
- ANOS1 | c.258C>T p.C86= | Splice Region (SNP) | VAF 85/259 reads (33%) | catalogued as COSV52925174; called by muse, mutect2, varscan2
- APCS | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54817330; called by muse, mutect2, varscan2
- ARHGAP22 | c.1890C>G p.D630E | Missense Mutation (SNP) | VAF 135/484 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV50974326; called by muse, mutect2, varscan2
- ASH1L | c.3645G>T p.E1215D | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1332354740, COSV100853420, COSV64212648; called by muse, mutect2, varscan2
- ASPN | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564330399, COSV65016018; called by muse, mutect2, varscan2
- ATF7IP2 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61095107; called by muse, mutect2, varscan2
- BCAR3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs756308329, COSV53078432; called by muse, mutect2, varscan2
- BCHE | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1394488716, COSV52261007; called by muse, mutect2, varscan2
- BCL7B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as rs782334386, COSV56270029; called by muse, mutect2, varscan2
- BCORL1 | c.3621G>T p.K1207N | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54392355, COSV54393705; called by muse, mutect2, varscan2
- BPNT1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs753054605, COSV59040605; called by muse, mutect2, varscan2
- BRSK2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1465081253, COSV57548034; called by muse, mutect2, varscan2
- CACNA1F | c.4678C>T p.R1560W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs782017505, COSV59905131; called by muse, mutect2, varscan2
- CACNA1G | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as rs1438217441, COSV61736267; called by muse, mutect2, varscan2
- CD36 | c.1195dup p.I399Nfs*19 | Frame Shift Ins (INS) | VAF 80/287 reads (28%) | catalogued as rs753754773; called by mutect2, pindel, varscan2
- CDH4 | c.2251C>A p.L751M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); catalogued as COSV64671133; called by muse, mutect2, varscan2
- CDH8 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104408049, COSV54845838; called by muse, mutect2, varscan2
- CDR2 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202476727, COSV51677299; called by muse, mutect2, varscan2
- CFHR3 | c.126C>A p.Y42* | Nonsense Mutation (SNP) | VAF 88/284 reads (31%) | catalogued as COSV66403135; called by muse, mutect2, varscan2
- CHD5 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52423161; called by muse, mutect2, varscan2
- CHRNA2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 166/541 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs774054592, COSV53557297; called by mutect2, varscan2
- CHRNA7 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296329119, COSV60975191; called by muse, mutect2, varscan2
- CNTN6 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63186458; called by muse, mutect2, varscan2
- CNTNAP5 | c.3435G>T p.E1145D | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV70507737, COSV70511265; called by muse, mutect2, varscan2
- CPXM2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747723133, COSV53864980; called by muse, mutect2, varscan2
- CSMD3 | c.10798G>T p.D3600Y (on ENST00000297405 / NM_001363185.1; = p.D3431Y on NM_052900.3) | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52291628, COSV52336815; called by muse, mutect2, varscan2
- CSMD3 | c.3489T>G p.F1163L (on ENST00000297405 / NM_001363185.1; = p.F1059L on NM_052900.3) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52229369; called by muse, mutect2, varscan2
- DBF4 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs756460174, COSV55998521; called by muse, mutect2, varscan2
- DDHD2 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.684); catalogued as COSV68158624; called by muse, mutect2
- DNAH9 | c.8137C>T p.R2713* | Nonsense Mutation (SNP) | VAF 128/418 reads (31%) | catalogued as rs760609171, COSV52348055, COSV99303461; called by muse, mutect2, varscan2
- EFCAB13 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 115/340 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs202126404, COSV58951945; called by muse, mutect2, varscan2
- ELMOD1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201382091; called by muse, mutect2, varscan2
- EMB | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs375679309; called by muse, mutect2, varscan2
- FAT4 | c.11314C>A p.H3772N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58704011; called by muse, mutect2, varscan2
- FGD6 | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269009624, COSV59696433; called by muse, mutect2, varscan2
- FOXA2 | c.669del p.D225Tfs*39 (on ENST00000377115 / NM_153675.3; = p.D231Tfs*39 on NM_021784.5) | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as COSV65796977, COSV65797063; called by mutect2, pindel, varscan2
- GABRA3 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64804078; called by muse, mutect2, varscan2
- GC | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV56739451; called by muse, mutect2, varscan2
- GNLY | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs767011139, COSV55702969; called by muse, mutect2, varscan2
- GOLGB1 | c.7140A>T p.K2380N | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61469965; called by muse, mutect2, varscan2
- H3C6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs776406667, COSV64519844; called by muse, mutect2, varscan2
- HAPLN2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54816493; called by muse, mutect2, varscan2
- HDX | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV52981459, COSV52981980; called by muse, mutect2, varscan2
- HEATR1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV63982744; called by muse, mutect2, varscan2
- HOXC10 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as rs368239850; called by muse, mutect2, varscan2
- ITPR1 | c.7717T>C p.F2573L (on ENST00000354582; = p.F2518L on NM_002222.7) | Missense Mutation (SNP) | VAF 123/476 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56999873; called by muse, mutect2, varscan2
- KCNJ3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1214174573, COSV54534893, COSV54540893; called by muse, mutect2, varscan2
- KCNQ3 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV66480041; called by muse, mutect2, varscan2
- KLHL4 | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV64146915; called by muse, mutect2, varscan2
- KLHL8 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 81/220 reads (37%) | catalogued as rs549853074, COSV56747892; called by muse, mutect2, varscan2
- KRT15 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 181/581 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV54181551; called by muse, mutect2, varscan2
- L1TD1 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); catalogued as rs1458397697, COSV63134188; called by muse, mutect2, varscan2
- LAMA5 | c.9107G>A p.R3036H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs749079447, COSV53360648; called by muse, mutect2, varscan2
- LRP1 | c.10511C>T p.S3504L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs142721778; called by muse, mutect2, varscan2
- LRP6 | c.3773C>T p.T1258M | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs746427916, COSV53786012; called by muse, mutect2, varscan2
- LRRN4 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV66646175, COSV66646358; called by muse, mutect2, varscan2
- LUM | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57127889, COSV57128713; called by muse, mutect2, varscan2
- MAGEE1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373804803, COSV63909530; called by muse, mutect2, varscan2
- MASP1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs115647447, COSV51459178; called by muse, mutect2, varscan2
- MED12L | c.5284A>C p.T1762P | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV56393640; called by muse, mutect2, varscan2
- MOB1B | c.181+1G>A p.X61_splice | Splice Site (SNP) | VAF 72/216 reads (33%) | catalogued as COSV58673577, COSV58675044; called by muse, mutect2, varscan2
- MORC4 | c.2543G>T p.R848I | Missense Mutation (SNP) | VAF 166/578 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV55243368, COSV55245917; called by muse, mutect2, varscan2
- MRPS27 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54652261; called by muse, mutect2, varscan2
- MYO10 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV72454665; called by muse, mutect2, varscan2
- MYT1 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60511940; called by muse, varscan2
- NAA11 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54515673; called by muse, mutect2, varscan2
- NAV2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV62332389; called by muse, mutect2, varscan2
- NAV2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.114); catalogued as rs1445774646, COSV62332399; called by muse, mutect2, varscan2
- NCKAP1L | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779642333, COSV53206082; called by muse, mutect2, varscan2
- NEUROD4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as rs1348950205, COSV54473749; called by muse, mutect2, varscan2
- NGB | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53611823; called by muse, mutect2, varscan2
- NLGN1 | c.1686C>A p.F562L | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as rs1346882966, COSV100849559, COSV64344450; called by muse, mutect2, varscan2
- NLRP7 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV60180588; called by muse, mutect2, varscan2
- NPAP1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.438); catalogued as rs1277274517, COSV61505858; called by muse, mutect2
- OR2M7 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV58737774; called by muse, mutect2, varscan2
- OR4C15 | c.326T>C p.V109A (on ENST00000314644; = p.V55A on NM_001001920.2) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58952283; called by muse, mutect2
- OR4K2 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 96/503 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV53851233; called by muse, mutect2, varscan2
- OR4K5 | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 120/553 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV60002404, COSV60004958; called by muse, mutect2, varscan2
- OR51A7 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376011053, COSV63788522; called by muse, mutect2, varscan2
- OR52N2 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 218/753 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.764); catalogued as COSV57677662; called by muse, mutect2, varscan2
- OR5F1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs756763105, COSV53548362; called by muse, mutect2, varscan2
- OR5H14 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV71193429, COSV71193841; called by muse, mutect2, varscan2
- PALD1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1236381462, COSV54978035, COSV99698191; called by muse, mutect2
- PCDH10 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52102157; called by muse, mutect2, varscan2
- PCDH15 | c.4782G>T p.E1594D | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated, low confidence (0.73); catalogued as COSV64727369; called by muse, mutect2, varscan2
- PCDH15 | c.5710G>T p.E1904* | Nonsense Mutation (SNP) | VAF 163/585 reads (28%) | catalogued as COSV57378267; called by muse, mutect2, varscan2
- PCLO | c.1788A>C p.E596D | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.879); catalogued as COSV61660042; called by muse, varscan2
- PDC | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV60854770; called by muse, mutect2, varscan2
- PDE9A | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.156); catalogued as COSV52330557; called by muse, mutect2, varscan2
- PDYN | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV54103201; called by muse, mutect2, varscan2
- PLA2G4C | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV62787496; called by muse, mutect2, varscan2
- PLB1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752545430, COSV59833879; called by muse, mutect2
- PLEKHG4B | c.1466G>A p.R489H (on ENST00000283426; = p.R845H on NM_052909.5) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs529537081, COSV52049819; called by muse, mutect2, varscan2
- PLXNB2 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs532944576, COSV63783105, COSV63783937; called by muse, mutect2, varscan2
- POLA1 | c.3365A>G p.N1122S | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV66890078; called by muse, mutect2, varscan2
- POLR2B | c.3152T>C p.L1051S | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58902385; called by muse, mutect2, varscan2
- PRG4 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV66625364; called by muse, mutect2, varscan2
- PRKD2 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as rs775481750, COSV52189202; called by muse, mutect2, varscan2
- PRKG2 | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52330624; called by muse, mutect2, varscan2
- RAD9B | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62195406; called by muse, mutect2, varscan2
- REV3L | c.5494G>A p.V1832M | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs768017978, COSV62614969; called by muse, mutect2, varscan2
- RPGR | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 162/571 reads (28%) | catalogued as COSV58839217; called by muse, mutect2, varscan2
- RTN4RL2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs755532417, COSV58652864; called by muse, mutect2, varscan2
- RUNX1T1 | c.904T>G p.L302V (on ENST00000265814 / NM_001198628.1; = p.L275V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/450 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as COSV56141173; called by muse, mutect2, varscan2
- SACS | c.6709G>A p.E2237K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs768517084, COSV66545804; called by muse, mutect2, varscan2
- SBNO1 | c.4006C>T p.R1336W (on ENST00000420886; = p.R1335W on NM_018183.5) | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57339340; called by muse, mutect2, varscan2
- SEMA3E | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57105292; called by muse, mutect2, varscan2
- SHANK1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.551); catalogued as rs780734174, COSV53260228, COSV53260785; called by muse, mutect2, varscan2
- SIN3A | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 77/256 reads (30%) | catalogued as COSV64583106; called by muse, mutect2, varscan2
- SLC2A13 | c.1802A>C p.K601T | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV55126333; called by muse, mutect2, varscan2
- SLC35G5 | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.373); catalogued as rs745802136, COSV55312314; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2209G>A p.D737N (on ENST00000540229 / NM_001371097.1; = p.D676N on NM_001009562.4) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951327157, COSV67446610; called by muse, mutect2, varscan2
- SLTM | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51054363, COSV99989323; called by muse, mutect2, varscan2
- SMURF1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); catalogued as COSV63159343; called by muse, mutect2, varscan2
- SORL1 | c.4418G>A p.R1473Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs765054279, COSV52758244; called by muse, mutect2, varscan2
- SRF | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54839740, COSV99541839; called by muse, mutect2, varscan2
- SVEP1 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57045390; called by muse, mutect2
- TDP1 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as rs1555382978, COSV59645236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD7 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377340161, COSV62428261, COSV62430238; called by muse, mutect2, varscan2
- TEX47 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs749960309, COSV51880091; called by muse, mutect2, varscan2
- TMC2 | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs769104197, COSV62657365; called by muse, mutect2, varscan2
- TNKS | c.1579-1G>A p.X527_splice | Splice Site (SNP) | VAF 134/483 reads (28%) | catalogued as COSV60065018; called by muse, mutect2, varscan2
- TTN | c.69017G>A p.R23006Q (on ENST00000591111; = p.R15582Q on NM_003319.4) | Missense Mutation (SNP) | VAF 64/206 reads (31%) | PolyPhen possibly damaging (0.612); catalogued as rs767512581, COSV59928136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWF1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs201989375, COSV57301736; called by muse, mutect2, varscan2
- UAP1 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV54853110; called by muse, mutect2, varscan2
- USP44 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 74/248 reads (30%) | catalogued as COSV51566436; called by muse, mutect2, varscan2
- UTP14A | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV64087776; called by muse, mutect2, varscan2
- UTP6 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs762194464, COSV55572493; called by muse, mutect2, varscan2
- UTRN | c.7989A>T p.K2663N | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV62312191; called by muse, mutect2, varscan2
- WDR72 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV64752703; called by muse, mutect2, varscan2
- XIRP2 | c.5462C>A p.T1821N (on ENST00000628543; = p.T1996N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV54728337; called by muse, mutect2, varscan2
- XPO7 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV53019250; called by muse, mutect2, varscan2
- ZBTB33 | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58534912; called by muse, mutect2, varscan2
- ZNF189 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs753951390, COSV52276635; called by muse, mutect2, varscan2
- ZNF267 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56250735, COSV56251800; called by muse, mutect2, varscan2
- ZNF41 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57444840; called by muse, mutect2, varscan2
- ZNF527 | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1264868492, COSV62234469; called by muse, mutect2, varscan2
- ZNF551 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56594687; called by muse, mutect2, varscan2
- ZNF615 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs781201122, COSV65032289, COSV65033860; called by muse, mutect2, varscan2
- ZNF674 | c.1214G>T p.R405I | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV70378554, COSV70378809; called by muse, mutect2, varscan2
- ZNF831 | c.4655G>T p.R1552I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV64044385; called by muse, mutect2, varscan2
- ZNF836 | c.2561G>T p.R854I | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs766728946, COSV59081194; called by muse, mutect2, varscan2
- FRG2C | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 114/1308 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2
- IGKV1-16 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 111/402 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PTEN | c.170dup p.L57Ffs*6 | Frame Shift Ins (INS) | VAF 30/122 reads (25%) | called by mutect2, pindel, varscan2
- UNC5C | c.649dup p.Y217Lfs*5 | Frame Shift Ins (INS) | VAF 65/263 reads (25%) | called by mutect2, pindel, varscan2
- ACO1 | c.909C>T p.Y303= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as rs370738336; called by muse, mutect2, varscan2
- ACTRT1 | c.837C>A p.V279= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV64419156; called by muse, mutect2, varscan2
- ADTRP | c.108C>A p.I36= | Silent (SNP) | VAF 144/537 reads (27%) | catalogued as COSV57645490; called by muse, mutect2, varscan2
- ANAPC5 | c.582A>G p.V194= | Silent (SNP) | VAF 39/620 reads (6%) | catalogued as COSV55844951; called by muse, mutect2
- AP1G1 | c.2337A>G p.T779= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as rs760924711, COSV55490768, COSV55494315; called by muse, mutect2, varscan2
- ATP9A | c.3021C>T p.I1007= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as rs778864183, COSV58770891; called by muse, mutect2, varscan2
- BOD1L1 | c.6456C>T p.F2152= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs139854434, COSV50007842; called by muse, mutect2, varscan2
- C5 | c.372A>G p.G124= | Silent (SNP) | VAF 75/240 reads (31%) | catalogued as COSV56331397; called by muse, mutect2, varscan2
- CACNA1S | c.567C>A p.I189= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV62942892; called by muse, mutect2
- CCPG1 | c.1629C>A p.I543= | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as rs1397414594, COSV51243711; called by muse, mutect2, varscan2
- CLGN | c.1497A>G p.K499= | Silent (SNP) | VAF 117/378 reads (31%) | catalogued as rs370853657; called by muse, mutect2, varscan2
- COL9A3 | c.1986C>T p.C662= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs139796454; called by muse, mutect2, varscan2
- CSMD3 | c.9612G>A p.T3204= (on ENST00000297405 / NM_001363185.1; = p.T3035= on NM_052900.3) | Silent (SNP) | VAF 103/309 reads (33%) | catalogued as rs183191388; called by muse, mutect2, varscan2
- CYP1A2 | c.678C>T p.F226= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV59659773; called by muse, mutect2, varscan2
- ENAM | c.753G>A p.T251= | Silent (SNP) | VAF 72/275 reads (26%) | catalogued as rs760680070, COSV68535329; called by muse, mutect2, varscan2
- FAM161A | c.1944G>A p.E648= | Silent (SNP) | VAF 162/544 reads (30%) | catalogued as COSV68326757; called by muse, mutect2, varscan2
- FLG2 | c.2532C>T p.S844= | Silent (SNP) | VAF 51/324 reads (16%) | catalogued as COSV66172169; called by muse, mutect2, varscan2
- FXYD5 | c.315G>A p.T105= | Silent (SNP) | VAF 127/412 reads (31%) | catalogued as rs775766253, COSV61568455; called by muse, mutect2, varscan2
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2, varscan2
- GTF3C5 | c.651C>A p.I217= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV59601658; called by muse, mutect2, varscan2
- GULP1 | c.390C>T p.S130= | Silent (SNP) | VAF 82/283 reads (29%) | catalogued as rs564290784, COSV63065554; called by muse, mutect2, varscan2
- HIRA | c.2688G>A p.S896= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs781832172, COSV54278551, COSV99601054; called by muse, mutect2
- HNRNPA3 | c.393T>C p.G131= | Silent (SNP) | VAF 97/299 reads (32%) | catalogued as rs750150123, COSV66820785; called by muse, mutect2, varscan2
- HS3ST5 | c.900C>A p.I300= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV57134597, COSV57139498; called by muse, mutect2, varscan2
- IGHD | c.759T>C p.H253= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66655436; called by muse, mutect2, varscan2
- IGHD3-16 | c.25T>C p.L9= | Silent (SNP) | VAF 102/380 reads (27%) | called by muse, mutect2
- ITPR1 | c.8130G>A p.T2710= (on ENST00000354582; = p.T2655= on NM_002222.7) | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs368813104; called by muse, mutect2, varscan2
- JPH2 | c.1926T>C p.A642= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV65905332; called by muse, mutect2, varscan2
- L1CAM | c.1260C>T p.Y420= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs782342513, COSV62829740; called by muse, mutect2, varscan2
- LINGO1 | c.318C>T p.I106= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs757183151, COSV62438192; called by muse, mutect2, varscan2
- MARK4 | c.270C>T p.I90= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs767329288, COSV53467941; called by muse, mutect2, varscan2
- MAT1A | c.837T>C p.G279= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1350927174, COSV64746806; called by muse, mutect2, varscan2
- MCM10 | c.1383C>T p.Y461= (on ENST00000484800 / NM_182751.3; = p.Y460= on NM_018518.5) | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs772514646, COSV66336396; ClinVar: likely benign; called by muse, mutect2, varscan2
- MICAL1 | c.369C>T p.N123= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs144274960; called by muse, mutect2
- MKI67 | c.4719A>G p.R1573= | Silent (SNP) | VAF 17/588 reads (3%) | catalogued as rs1323345084, COSV64076391; called by muse, mutect2
- NCOA3 | c.3357G>A p.G1119= | Silent (SNP) | VAF 68/209 reads (33%) | catalogued as COSV59072540; called by muse, mutect2, varscan2
- NDUFB11 | c.360C>T p.R120= (on ENST00000377811 / NM_001135998.3; = p.R130= on NM_019056.6) | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as rs199726768, COSV52102661; called by muse, mutect2, varscan2
- NF1 | c.5664C>T p.I1888= (on ENST00000358273 / NM_001042492.3; = p.I1867= on NM_000267.3) | Silent (SNP) | VAF 69/285 reads (24%) | catalogued as rs373685150; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRG3 | c.2022C>T p.Y674= (on ENST00000404547 / NM_001370084.1; = p.Y650= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs376987579; called by muse, mutect2, varscan2
- PIGR | c.1551C>T p.F517= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as rs549583756, COSV62904846; called by muse, mutect2, varscan2
- PLP2 | c.339C>T p.V113= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as COSV66240553; called by muse, mutect2, varscan2
- PLXNB3 | c.4293G>A p.A1431= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs782290949, COSV62801292; called by muse, mutect2, varscan2
- PSAPL1 | c.177G>A p.A59= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs745451911, COSV59842696; called by muse, mutect2
- RAD23A | c.906C>T p.G302= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs141855300; called by muse, mutect2, varscan2
- RAD52 | c.891G>A p.T297= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs373796726; called by muse, mutect2, varscan2
- RNF44 | c.1026C>T p.N342= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV51270937; called by muse, mutect2, varscan2
- SLC8A1 | c.2286C>T p.D762= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as rs781045590, COSV60474040; called by muse, mutect2, varscan2
- SMOC2 | c.1191C>T p.D397= (on ENST00000356284 / NM_001166412.2; = p.D408= on NM_022138.3) | Silent (SNP) | VAF 72/231 reads (31%) | catalogued as rs368747279; called by muse, mutect2, varscan2
- TENM3 | c.7800C>T p.F2600= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV69304100; called by muse, mutect2
- THEMIS2 | c.1050G>A p.V350= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV61078341; called by muse, varscan2
- TLR5 | c.1479C>A p.L493= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as COSV60560454, COSV60561045; called by muse, mutect2, varscan2
- TMC7 | c.1722C>A p.I574= | Silent (SNP) | VAF 55/176 reads (31%) | catalogued as COSV58582924, COSV58587723; called by muse, mutect2, varscan2
- TPM1 | c.645G>A p.S215= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs773403386, COSV51266023; called by muse, mutect2, varscan2
- ZNF30 | c.1659A>G p.G553= | Silent (SNP) | VAF 56/193 reads (29%) | catalogued as COSV57855154; called by muse, mutect2, varscan2
- ZNF582 | c.1164T>C p.I388= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV56733493; called by muse, mutect2, varscan2
- ZNF711 | c.1047T>C p.N349= | Silent (SNP) | VAF 99/284 reads (35%) | catalogued as COSV52158215; called by muse, mutect2, varscan2
- MIR545 | n.10G>A | RNA (SNP) | VAF 56/176 reads (32%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23482A>C | Intron (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59396530; called by muse, mutect2, varscan2
